Gene-level copy-number profile of tumor specimen TCGA-AN-A0FY-01A from TCGA case TCGA-AN-A0FY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.7 years (20,347 days).
Specimen TCGA-AN-A0FY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.52ebb933-775a-448c-82ba-42fd1da8cf2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 845 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5d58498b-f897-490b-81bb-3b17b510d4bd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 995; copy number 2: 12,032; copy number 3: 19,484; copy number 4: 18,601; copy number 5: 3,944; copy number 6: 3,160; copy number 7: 830; copy number 8: 203; copy number 9: 1; copy number 10: 20; copy number 11: 74; copy number 12: 15; copy number 14: 6; copy number 15: 241; copy number 16: 19; copy number 17: 26; copy number 21: 38; copy number 25: 37; copy number 28: 1; copy number 30: 20; copy number 39: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FY-01A-11D-A036-01): tumor purity 0.74, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:13,494,032–14,069,495, 6 genes (within-gene range 0–2): HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,556 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,055,353–52,282,859, 15 genes, copy number 12: RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.
- chr9:452,492–1,333,953, 19 genes, copy number 7: AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279.
- chr9:12,685,439–13,836,571, 13 genes, copy number 8–11 (within-gene range 5–11): TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:20,331,446–23,898,054, 79 genes, copy number 8 (broad region; genes not listed).
- chr9:27,495,857–31,645,160, 33 genes, copy number 8: AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:32,676,063–43,045,120, 365 genes, copy number 7 (broad region; genes not listed).
- chr11:32,892,811–36,697,867, 81 genes, copy number 7 (broad region; genes not listed).
- chr13:56,051,034–57,991,464, 15 genes, copy number 7: AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30.
- chr13:72,703,693–94,408,020, 218 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr13:97,953,658–98,577,940, 11 genes, copy number 16 (within-gene range 5–16): IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1.
- chr19:27,757,184–32,106,544, 82 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr20:9,537,370–9,873,900, 4 genes, copy number 7 (within-gene range 3–7): PAK5, AL353612.2, AL353612.1, AL034427.1.
- chr20:15,892,355–20,360,703, 88 genes, copy number 7–14 (within-gene range 5–14) (broad region; genes not listed).
- chr20:22,054,074–25,868,225, 105 genes, copy number 7–10 (broad region; genes not listed).
- chr20:42,968,743–61,940,617, 428 genes, copy number 11–39 (within-gene range 2–39) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
